Gene-level copy-number profile of tumor specimen TCGA-97-7937-01A from TCGA case TCGA-97-7937, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Invasive micropapillary carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 65.5 years (23,919 days).
Specimen TCGA-97-7937-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.a163b78e-b83e-4e4b-9fdd-fede826ceb9e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-97-7937-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7bcb7883-edb2-4692-a90d-675c5a38e093

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 2: 1,742; copy number 3: 6,615; copy number 4: 13,921; copy number 5: 11,793; copy number 6: 10,211; copy number 7: 7,087; copy number 8: 4,053; copy number 9: 2,903; copy number 10: 416; copy number 12: 867; copy number 13: 9; copy number 14: 74; copy number 17: 38; copy number 22: 67; copy number 31: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-97-7937-01A-11D-2166-01): tumor purity 0.59, ploidy 2.82, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 4,390 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:223,373,822–223,864,851, 9 genes, copy number 13: RNU4-57P, CCDC185, CAPN8, SNRPEP10, RNU6-1248P, CAPN2, TP53BP2, PHBP11, ACTBP11.
- chr5:58,198–45,895,970, 710 genes, copy number 12 (broad region; genes not listed).
- chr5:52,579,555–54,645,987, 33 genes, copy number 9: MFSD4BP1, AC022126.1, PELO, ITGA1, AC022133.2, B3GNTL1P1, AC022133.1, AC025180.1, ITGA2, AC008966.3, AC008966.2, MOCS2, AC008966.1, AC026477.1, AC027329.1, AC108114.1, FST, NDUFS4, LINC02105, ASS1P9, AC025175.1, ARL15, AC025175.2, RNU6-272P, MIR581, RN7SL801P, AC016601.1, AC008873.1, LINC01033, RPL37P25, HSPB3, SNX18, AC016583.1.
- chr7:70,972–40,860,763, 726 genes, copy number 9–10 (within-gene range 8–10) (broad region; genes not listed).
- chr7:76,902,480–112,206,407, 602 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr10:44,712–38,762,491, 674 genes, copy number 9–12 (broad region; genes not listed).
- chr10:107,694,973–110,642,785, 28 genes, copy number 9 (within-gene range 6–9): LINC01435, PTGES3P5, AL353740.1, LINC02661, MAPKAPK5P1, RN7SKP278, RNU5B-6P, RNU6-839P, PHB2P1, BTF3P15, AL390123.1, XIAPP1, RPL21P91, XPNPEP1, RNU4-5P, ADD3-AS1, ADD3, SNRPGP12, MXI1, AL360182.2, AL360182.1, SMNDC1, AL355512.1, HMGB3P5, DUSP5, RPL7P35, SMC3, Y_RNA.
- chr14:33,597,057–40,905,513, 125 genes, copy number 10–31 (broad region; genes not listed).
- chr14:53,599,832–56,427,032, 52 genes, copy number 10: AL163953.1, RPS3AP46, LINC02331, AL138479.1, MIR5580, BMP4, AL138479.2, ATP5F1CP1, CDKN3, CNIH1, AL359792.1, GMFB, CGRRF1, SAMD4A, AL133444.1, GCH1, RNU6ATAC9P, MIR4308, FDPSP3, WDHD1, RPSAP13, SOCS4, MAPK1IP1L, LGALS3, DLGAP5, AL139316.1, AL158801.4, COX5AP1, AL158801.2, FBXO34, AL158801.1, Metazoa_SRP, CHMP4BP1, AL158801.3, ATG14, HMGN1P1, TBPL2, RPL21P6, KTN1-AS1, RPL7AP4, ABI1P1, KTN1, Y_RNA, AL355773.1, RPL13AP3, LINC00520, AL163952.1, AL138995.1, PELI2, AL355073.1, AL355073.2, LINC02284.
- chr20:1,023,874–64,313,132, 1,431 genes, copy number 9–14 (within-gene range 7–14) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
